Surgical pathology report (de-identified scan), TCGA case TCGA-N5-A4RO, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MSKCC, specimen TCGA-N5-A4RO-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinosarcoma / Mixed
Mullerian Tumor, malignant
8950/3
Site c&cf Uterus NOS
path Endometrium C55.9
C54.1
JW 4/2/13

Specimens Submitted:

- 1: SP: Uterus, tubes, ovaries, cervix
- 2: SP: Left external iliac node
- 3: SP: Left obturator node
- 4: SP: Right external iliac node
- 5: SP: Right obturator node
- 6: SP: Right peri-aortic node
- 7: SP: Left peri-aortic mass and lymph nodes

DIAGNOSIS:

- 1) UTERUS, TUBES, OVARIES AND CERVIX; HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- MALIGNANT MIXED MUELLERIAN TUMOR OF ENDOMETRIUM, WITHOUT HETEROLOGOUS ELEMENTS. THE CARCINOMATOUS COMPONENT DOMINATES AND IS OF SEROUS HISTOLOGY. THE TUMOR INVADES TO > HALF OF MYOMETRIUM. THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 1.7 MM. THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 1.8 MM. NO ENDOCERVICAL INVASION IS IDENTIFIED. DIFFUSE VASCULAR INVASION IS PRESENT. THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY(IES): ATROPHY. THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY(IES): LEIOMYOMA(S), SUBSEROUSAL, WITH TUMOR EMBOLI. THE RIGHT AND LEFT FALLOPIAN TUBES SHOW ATROPHY. THE RIGHT AND LEFT OVARIES SHOW CORPORA ALBICANTIA. THE LEFT AND RIGHT PARAMETRIA ARE POSITIVE FOR TUMOR.
- 2) LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION:
- METASTATIC CARCINOMA TO ONE OUT OF THREE LYMPH NODES (1/3).
- 3) LYMPH NODE, LEFT OBTURATOR; EXCISION:
- METASTATIC CARCINOMA TO ONE OUT OF ONE LYMPH NODE (1/1), WITH EXTRACAPSULAR EXTENSION.
- 4) LYMPH NODES, RIGHT EXTERNAL ILIAC; EXCISION:
- METASTATIC CARCINOMA TO FIVE OUT OF FIVE LYMPH NODES (5/5).
- 5) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- METASTATIC CARCINOMA TO TWO OUT OF FOUR LYMPH NODES (2/4).

PATH
REPORT

** Continued on next page **

[page 2 of 2]
- [REDACTED]
- 6) LYMPH NODES, RIGHT PERIAORTIC; EXCISION:
- METASTATIC CARCINOMA TO THREE OUT OF THREE LYMPH NODES
(3/3).
- 7) LYMPH NODES AND SOFT TISSUE, LEFT PERIAORTIC; EXCISION:
- METASTATIC CARCINOMA TO TWO OUT OF SEVEN LYMPH NODES
(2/7).
- [REDACTED]

** Report Electronically Signed Out **

[REDACTED]

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION
OF THE SLIDES (AND/OR OTHER
MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Source: NCI Genomic Data Commons file 8eb07a3c-ec46-4ac6-8bd8-9eabd0c58572 (TCGA-N5-A4RO.EB1B2478-CC59-427E-B548-ED14C4116E46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).